Somatic mutation profile of tumor specimen TCGA-EU-5907-01A (aliquot TCGA-EU-5907-01A-11D-1669-08) from TCGA case TCGA-EU-5907, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 81.8 years (29,863 days).
Specimen TCGA-EU-5907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8993b8ed-8b5e-4c5c-a895-db172f79e4ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EU-5907-10A (Blood Derived Normal), aliquot TCGA-EU-5907-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4d2b345-ad00-4100-89a0-6858fd042d65

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.258del p.V87Yfs*72 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs864622545, CM951276, CM952019, COSV56546515, COSV56547374, COSV56564109; ClinVar: pathogenic; called by mutect2, varscan2
- ATG4C | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV58608557; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1283T>C p.I428T | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.219); catalogued as rs763645512, COSV52355334; called by muse, mutect2, varscan2
- CHST11 | c.93del p.Y32Ifs*54 | Frame Shift Del (DEL) | VAF 65/172 reads (38%) | catalogued as COSV57996393; called by mutect2, pindel, varscan2
- DDX18 | c.371-2A>G p.X124_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as COSV54309280; called by muse, mutect2, varscan2
- EIF3A | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299009750, COSV64963529; called by muse, mutect2, varscan2
- EIF3L | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67740150; called by muse, mutect2, varscan2
- EPB41L1 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757647901, COSV52445221; called by muse, mutect2, varscan2
- HPS5 | c.3167G>C p.G1056A (on ENST00000349215 / NM_181507.2; = p.G942A on NM_007216.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV61688071; called by muse, mutect2, varscan2
- KRT23 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 65/142 reads (46%) | catalogued as rs370055839; called by muse, mutect2, varscan2
- MET | c.1510G>C p.V504L | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.338); catalogued as COSV59269527; called by muse, mutect2, varscan2
- MRPL2 | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52439291; called by muse, mutect2, varscan2
- MYH4 | c.932A>T p.Y311F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV55126598, COSV99700820; called by muse, mutect2, varscan2
- MYH4 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55126610; called by muse, mutect2, varscan2
- MYH4 | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1467462249, COSV55126624; called by muse, mutect2, varscan2
- MYO3A | c.3965G>T p.G1322V | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV56350183; called by muse, mutect2
- NGFR | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.26); catalogued as COSV50804596; called by muse, mutect2, varscan2
- NYNRIN | c.4046C>T p.T1349M | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs538061448, COSV66843292; called by muse, mutect2, varscan2
- PBRM1 | c.1505C>G p.S502* | Nonsense Mutation (SNP) | VAF 53/63 reads (84%) | catalogued as COSV56305318; called by muse, mutect2, varscan2
- PHF23 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 259/653 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV50039817; called by muse, mutect2, varscan2
- PI4KB | c.1024C>G p.L342V (on ENST00000368873 / NM_001369623.1; = p.L354V on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV55021432; called by muse, mutect2, varscan2
- PIGT | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54129082; called by muse, varscan2
- PTEN | c.364_377del p.I122Wfs*53 | Frame Shift Del (DEL) | VAF 63/100 reads (63%) | catalogued as COSV64307394; called by mutect2, pindel, varscan2
- RABGGTA | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53771875; called by muse, mutect2, varscan2
- SLC8A2 | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52643073; called by muse, mutect2, varscan2
- SLIT2 | c.1921C>A p.Q641K | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.22); PolyPhen benign (0.219); catalogued as rs553808717, COSV56596129; called by muse, mutect2, varscan2
- SPEN | c.3482T>C p.I1161T | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV65367600; called by muse, mutect2, varscan2
- SPSB2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | catalogued as COSV51290431; called by muse, mutect2, varscan2
- THSD7B | c.4288G>A p.G1430S (on ENST00000272643; = p.G1428S on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55739267; called by muse, mutect2, varscan2
- TMEM108 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as rs866075699, COSV58883543; called by muse, mutect2
- TMEM123 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 139/328 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs373043680; called by muse, mutect2, varscan2
- UNC5A | c.2020-1G>A p.X674_splice | Splice Site (SNP) | VAF 37/122 reads (30%) | catalogued as COSV52844818; called by muse, mutect2, varscan2
- ZMIZ1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs766908812, COSV57904174; called by muse, mutect2, varscan2
- AASS | c.2561_2562delinsC p.K854Tfs*42 | Frame Shift Del (DEL) | VAF 105/632 reads (17%) | called by pindel, varscan2*
- DLST | c.507dup p.A170Sfs*43 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- SLC22A12 | c.1555_1578del p.Q519_T526del | In Frame Del (DEL) | VAF 28/154 reads (18%) | called by mutect2, pindel
- SLC22A9 | c.270_271insGCGCGC p.R90_F91insAR | In Frame Ins (INS) | VAF 38/129 reads (29%) | called by mutect2, pindel, varscan2
- THBS2 | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TK1 | c.585_596del p.Q196_G199del | In Frame Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- TRAV41 | c.14G>C p.R5P | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- COL6A3 | c.8403C>G p.S2801= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV55110833; called by muse, mutect2, varscan2
- ENTPD4 | c.129T>C p.A43= | Silent (SNP) | VAF 13/207 reads (6%) | catalogued as COSV62270332; called by muse, mutect2
- FAM216B | c.288A>C p.S96= | Silent (SNP) | VAF 75/176 reads (43%) | catalogued as COSV58270050, COSV58271556; called by muse, mutect2, varscan2
- FOXD1 | c.534G>A p.S178= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as rs1052207; called by muse, mutect2, varscan2
- GOLPH3 | c.894G>A p.K298= | Silent (SNP) | VAF 85/354 reads (24%) | catalogued as COSV54062706; called by muse, mutect2, varscan2
- IL12RB1 | c.366G>A p.Q122= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs1158141873, COSV100443243, COSV59099507; called by muse, mutect2, varscan2
- PIGT | c.264A>G p.S88= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs771684622, COSV54125725, COSV54129063; called by muse, varscan2
- PKHD1L1 | c.8328C>T p.D2776= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs376156063; called by muse, mutect2, varscan2
- PLEKHG7 | c.981T>C p.Y327= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV60822853; called by muse, mutect2
- SPATA31D1 | c.420C>A p.I140= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV61201595; called by muse, mutect2, varscan2
- TMPRSS9 | c.1737C>T p.C579= (on ENST00000648592; = p.C545= on NM_182973.2) | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV100211152, COSV60231572; called by muse, mutect2
